Somatic mutation profile of tumor specimen ALCH-B2PW-TTP1-A (aliquot ALCH-B2PW-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2PW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.7 years (19,971 days).
Specimen ALCH-B2PW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40ac8674-31ae-4c22-bedb-bebe52cde4f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2PW-NB1-A (Blood Derived Normal), aliquot ALCH-B2PW-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5779f4d-535f-41e3-93a6-aaa45fa72356

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Nonsense Mutation 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CKAP4 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs374793071; called by muse, mutect2, varscan2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 59/290 reads (20%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- HEPACAM2 | c.530G>T p.R177L (on ENST00000394468 / NM_001039372.4; = p.R165L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/552 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100506714, COSV59062912; called by muse, mutect2
- HIVEP3 | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1279280308; called by muse, mutect2, varscan2
- OR2L5 | c.314C>A p.T105N | Missense Mutation (SNP) | VAF 103/274 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1334097734; called by muse, mutect2, varscan2
- PTPRQ | c.4433T>C p.I1478T (on ENST00000616559; = p.I1436T on NM_001145026.2) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs1256856879; called by muse, mutect2
- CCDC112 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- FAM131A | c.664C>G p.L222V (on ENST00000310585; = p.L253V on NM_144635.5) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- LTK | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.3812C>T p.T1271I | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NCF1 | c.524T>A p.M175K | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- PIP4P2 | c.140G>C p.S47T | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SNRK | c.1646A>G p.E549G | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SRPRB | c.328G>C p.G110R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- TRAV9-2 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- TWIST1 | c.515T>C p.M172T | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BHLHA15 | c.135G>A p.P45= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs564004252; called by muse, mutect2, varscan2
- CD1D | c.870C>T p.D290= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- MEFV | c.1605G>A p.L535= | Silent (SNP) | VAF 43/199 reads (22%) | called by muse, mutect2, varscan2
- MITF | c.957C>T p.N319= (on ENST00000448226 / NM_006722.3; = p.N219= on NM_000248.4) | Silent (SNP) | VAF 59/305 reads (19%) | catalogued as COSV58830721; called by muse, mutect2, varscan2
- NAV3 | c.1173C>A p.V391= | Silent (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- RASGRF2 | c.864C>T p.D288= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs368702145; called by muse, mutect2
- SI | c.2388C>T p.I796= | Silent (SNP) | VAF 14/310 reads (5%) | catalogued as COSV52269258; called by muse, mutect2
- DKC1 | c.-38G>T | 5'UTR (SNP) | VAF 53/141 reads (38%) | called by muse, mutect2, varscan2
